TCGA case TCGA-61-2096 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6beaa1cb-a9f1-4127-898c-7aff2273788e

Demographics
Sex at birth: female; Race: white; Age at index: 56 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 56.6 years (20,663 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IC; Tumor grade: G2; Prior treatment: No; Days to last follow up: 1,776 days (4.9 years).
   Pathology details: Residual tumor measurement: No macroscopic disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 79 days; Number of cycles: 3; Treatment dose: 1,440 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 79 days; Number of cycles: 3; Treatment dose: 645 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 474 days (1.3 years); Days to treatment end: 544 days (1.5 years); Number of cycles: 4; Treatment dose: 2,200 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 474 days (1.3 years); Days to treatment end: 544 days (1.5 years); Number of cycles: 4; Treatment dose: 1,296 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 916 days (2.5 years); Days to treatment end: 988 days (2.7 years); Number of cycles: 3; Treatment dose: 1,230 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Initial disease status: Recurrent Disease; Days to treatment start: 1,059 days (2.9 years); Days to treatment end: 1,156 days (3.2 years); Number of cycles: 5; Treatment dose: 1,876 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Recurrent Disease; Days to treatment start: 1,191 days (3.3 years); Days to treatment end: 1,372 days (3.8 years); Number of cycles: 6; Treatment dose: 1,430 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Initial disease status: Recurrent Disease; Days to treatment start: 1,191 days (3.3 years); Days to treatment end: 1,372 days (3.8 years); Number of cycles: 6; Treatment dose: 9,450 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Bevacizumab; Initial disease status: Recurrent Disease; Days to treatment start: 1,723 days (4.7 years); Days to treatment end: 2,010 days (5.5 years); Number of cycles: 4; Treatment dose: 5,320 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 1,723 days (4.7 years); Days to treatment end: 2,010 days (5.5 years); Number of cycles: 4; Treatment dose: 43 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Recurrent Disease; Days to treatment end: 642 days (1.8 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Melphalan; Initial disease status: Recurrent Disease; Days to treatment end: 642 days (1.8 years); Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment end: 642 days (1.8 years); Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 57.7 years (21,084 days); Days to diagnosis: 421 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (2 entries)
- Day 421 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 421 days (1.2 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,776 days (4.9 years); Disease response: Tumor Free.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-61-2096-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-61-2096-01A-01-BS1: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 70.
  Slide TCGA-61-2096-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 29.
- Sample TCGA-61-2096-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Anatomic organ subdivision: Right; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 4: Pharmaceutical therapy drug name: Avastin.
- Drug treatment 13: Pharmaceutical therapy drug name: Melphalon.
- Follow-up form: Treatment outcome first course: Progressive Disease; Tumor status: Tumor free.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: Pathology indicates Stage I disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,776 days; disease-specific survival: no event (censored), 1,776 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 421 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-61-2096-01A-01D-0663-01): tumor purity 0.91, ploidy 1.86, whole-genome doublings 0.
